Somatic mutation profile of tumor specimen MP2PRT-PASZUB-TMP1-A (aliquot MP2PRT-PASZUB-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASZUB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,385 days).
Specimen MP2PRT-PASZUB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3de198a-0587-4a7c-b48f-f3347fbcecc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZUB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZUB-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba55e0f2-8225-42e2-bb66-44c20dab9e3b

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 12, Silent 10, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, varscan2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2
- DSG1 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs543509156; called by muse, mutect2, varscan2
- NCAN | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370512552; called by muse, mutect2, varscan2
- OR51T1 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 78/532 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1243623017; called by muse, mutect2, varscan2
- TMOD1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs752063527, COSV52247986; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 152/310 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- WNK3 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 128/430 reads (30%) | catalogued as COSV63615456; called by muse, mutect2, varscan2
- DST | c.5624C>A p.S1875Y | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MAGEL2 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 401/1024 reads (39%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- NHSL2 | c.2017C>A p.L673M (on ENST00000510661; = p.L1039M on NM_001013627.2) | Missense Mutation (SNP) | VAF 67/701 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UGT2A3 | c.1378T>C p.F460L | Missense Mutation (SNP) | VAF 246/511 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UPRT | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 380/1275 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP15 | c.930A>G p.L310= | Silent (SNP) | VAF 79/161 reads (49%) | called by muse, mutect2, varscan2
- ATP10B | c.2151C>T p.Y717= | Silent (SNP) | VAF 93/670 reads (14%) | catalogued as rs369712825; called by muse, mutect2, varscan2
- ETV1 | c.792A>G p.A264= | Silent (SNP) | VAF 101/355 reads (28%) | called by muse, mutect2, varscan2
- FAT1 | c.5757C>T p.T1919= | Silent (SNP) | VAF 192/421 reads (46%) | catalogued as rs779716177, COSV71671709; called by muse, mutect2, varscan2
- LRP2 | c.11778A>G p.K3926= | Silent (SNP) | VAF 161/324 reads (50%) | called by muse, mutect2, varscan2
- MPZL1 | c.462C>T p.V154= | Silent (SNP) | VAF 30/231 reads (13%) | catalogued as rs994503458; called by muse, mutect2, varscan2
- MSANTD1 | c.483G>A p.S161= | Silent (SNP) | VAF 73/874 reads (8%) | catalogued as rs765183366, COSV70873273; called by muse, mutect2
- PROB1 | c.12G>A p.A4= | Silent (SNP) | VAF 27/622 reads (4%) | called by muse, mutect2
- PUS3 | c.696C>T p.N232= | Silent (SNP) | VAF 48/612 reads (8%) | catalogued as rs140780584; called by muse, mutect2
- VAX1 | c.570G>A p.P190= | Silent (SNP) | VAF 120/606 reads (20%) | catalogued as COSV99524321; called by muse, varscan2
